EXCEPTIONAL_RESPONDERS case ER-B055 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f660ab21-fd73-4307-8bec-b94159ac7043

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1936; Vital status: Alive.

Diagnoses (2)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; Tissue or organ of origin: Extrahepatic bile duct; Site of resection or biopsy: Extrahepatic bile duct; Classification of tumor: metastasis; Age at diagnosis: 78.6 years (28,697 days); Year of diagnosis: 2015; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 758 days (2.1 years); Days to best overall response: 409 days (1.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cisplatin + Gemcitabine Hydrochloride; Days to treatment start: 35 days; Days to treatment end: 322 days.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,492 days).

Follow-up (1 entry)
- Days to follow up: 758 days (2.1 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 758 days (2.1 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B055-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B055-TTM2-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
